Gene-level copy-number profile of tumor specimen C3N-03664-01 from CPTAC case C3N-03664, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.5 years (21,361 days).
Specimen C3N-03664-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c8c1fe66-fa80-40a3-b60c-563bd64599c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03664-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/dd2a7791-2a11-441e-b2ac-f66f5dbec0db

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 463; copy number 1: 2,635; copy number 2: 20,067; copy number 3: 23,782; copy number 4: 8,949; copy number 5: 1,381; copy number 6: 604; copy number 7: 633; copy number 8: 14; copy number 9: 90; copy number 10: 201; copy number 14: 89.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:119,306,343–119,306,631, 1 gene (within-gene range 0–1): RN7SL174P.
- chr9:12,098,660–12,159,148, 1 gene: AL589678.1.
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,025 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:78,412,793–79,028,505, 7 genes, copy number 7: CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G.
- chr6:170,615,515–170,738,536, 1 gene, copy number 14 (within-gene range 3–14): AL672310.1.
- chr6:170,736,173–170,737,777, 1 gene, copy number 14: AL731684.1.
- chr8:35,862,123–39,417,378, 85 genes, copy number 14 (broad region; genes not listed).
- chr8:39,522,976–39,730,065, 2 genes, copy number 14: AC123767.1, ADAM18.
- chr8:43,018,424–43,674,591, 28 genes, copy number 7 (within-gene range 6–7): AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr9:34,810,020–36,487,548, 79 genes, copy number 10 (broad region; genes not listed).
- chr9:41,700,480–41,701,096, 2 genes, copy number 8: AL591926.1, AL591926.4.
- chr13:54,938,604–66,270,458, 79 genes, copy number 7–10 (broad region; genes not listed).
- chr13:67,266,845–75,482,169, 73 genes, copy number 7 (broad region; genes not listed).
- chr13:75,871,038–114,337,626, 456 genes, copy number 7–8 (broad region; genes not listed).
- chr14:33,924,227–41,149,309, 122 genes, copy number 9–10 (broad region; genes not listed).
- chr14:61,529,128–61,657,964, 1 gene, copy number 9 (within-gene range 6–9): AL355916.3.
- chr14:61,556,273–64,338,639, 46 genes, copy number 9: LINC01303, AL355916.1, HIF1A-AS1, HIF1A, HIF1A-AS3, AL137129.1, SNAPC1, AL137918.1, SYT16, COX4I1P1, AL390816.1, AL390816.2, LINC00643, LINC00644, AL390816.3, AL389895.1, ATP5F1AP4, KCNH5, AL137191.1, PARP1P2, RHOJ, AL049871.1, GPHB5, PPP2R5E, AL132992.1, AL136038.3, AL136038.1, GCATP1, WDR89, AL136038.2, HSPE1P2, RNU6-597P, Y_RNA, RNU6-1162P, AL136038.4, U3, SGPP1, EIF2S2P1, RNU7-116P, SYNE2, AL161670.1, RPS28P1, Y_RNA, ESR2, MIR548H1, AL161756.1.
- chr14:64,535,905–67,181,803, 43 genes, copy number 8–9 (within-gene range 5–9): HSPA2, PPP1R36, AL049869.1, NUP50P1, PLEKHG3, SPTB, MIR7855, RPPH1-2P, CHURC1, CHURC1-FNTB, GPX2, RAB15, FNTB, AL139022.2, MAX, MIR4706, AL139022.1, RNU2-14P, LINC02324, AL355076.3, AL355076.2, RPL21P7, AL355076.1, PTBP1P, MIR4708, FUT8, FUT8-AS1, RPL21P8, MIR625, EIF1AXP2, NCOA4P1, FTH1P13, AL391261.1, AL391261.2, YBX1P1, LINC02290, Y_RNA, AL359232.1, AL157997.1, CCDC196, GPHN, AL133241.1, AL049835.1.

Autosomal genes at a single copy (total copy number 1): 1,738. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
